Gene-level copy-number profile of tumor specimen TCGA-LN-A49V-01A from TCGA case TCGA-LN-A49V, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 49.1 years (17,922 days).
Specimen TCGA-LN-A49V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.f38ee567-6d95-4a0c-b9de-f75669da9605.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A49V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ce956a2d-2a53-4a3e-bcb3-d323972d41a5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4; copy number 2: 6,218; copy number 3: 3,615; copy number 4: 23,206; copy number 5: 7,192; copy number 6: 12,320; copy number 7: 1,180; copy number 8: 3,696; copy number 9: 431; copy number 10: 607; copy number 11: 334; copy number 12: 677; copy number 13: 26; copy number 14: 2; copy number 15: 101; copy number 24: 105; copy number 32: 24; copy number 34: 15; copy number 36: 56.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A49V-01A-11D-A246-01): tumor purity 0.92, ploidy 2.49, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,389,567–48,444,704, 1 gene (within-gene range 0–4): LPAR6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,378 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:162,069,691–164,980,137, 46 genes, copy number 9 (within-gene range 8–9): NOS1AP, AL450163.1, MIR4654, AL512785.1, RNA5SP61, MIR556, AL512785.2, SPATA46, C1orf226, SH2D1B, SLAMF6P1, UHMK1, UQCRBP2, AL596325.1, UAP1, AL596325.2, DDR2, RN7SL861P, HSD17B7, CCDC190, AL392003.2, AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P.
- chr1:237,042,184–240,698,429, 48 genes, copy number 9 (within-gene range 8–9): RYR2, RN7SKP195, MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA.
- chr5:173,607,145–173,773,164, 5 genes, copy number 10: BOD1, LINC01863, LINC01942, LINC01484, AC008674.1.
- chr5:180,899,077–181,342,213, 37 genes, copy number 15: BTNL8, Y_RNA, RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P, BTNL9, MIR8089, AC008620.1, FOXO1B, AC008620.2, OR2V1, OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, AC008443.7, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.6, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr6:19,143,695–24,809,798, 71 genes, copy number 24–36 (broad region; genes not listed).
- chr6:50,587,607–50,773,033, 2 genes, copy number 14 (within-gene range 6–14): AL135908.1, TFAP2D.
- chr7:54,933,699–55,713,252, 17 genes, copy number 11–34: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P.
- chr8:46,028,804–51,015,165, 77 genes, copy number 9 (broad region; genes not listed).
- chr8:56,496,048–58,272,450, 28 genes, copy number 9 (within-gene range 8–9): LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2, RNU6-13P, BPNT2, RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC068075.2, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2.
- chr8:70,471,112–145,066,685, 1,168 genes, copy number 9–12 (broad region; genes not listed).
- chr9:14,475–27,844,481, 373 genes, copy number 10–12 (broad region; genes not listed).
- chr11:10,302,657–10,507,579, 4 genes, copy number 12 (within-gene range 6–12): AC080023.1, ADM, AMPD3, RNU6ATAC33P.
- chr11:28,679,183–44,656,920, 209 genes, copy number 9–15 (broad region; genes not listed).
- chr11:55,262,155–57,515,780, 143 genes, copy number 9 (broad region; genes not listed).
- chr11:69,737,298–71,252,577, 34 genes, copy number 11–32 (within-gene range 3–32): DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr18:47,390–3,478,978, 85 genes, copy number 24 (broad region; genes not listed).
- chr18:3,571,215–3,656,282, 5 genes, copy number 24: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1.
- chr18:4,430,945–6,108,382, 24 genes, copy number 13 (within-gene range 5–13): AP005208.1, ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1, EPB41L3, AP005059.2, AP005059.1, MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3.
- chr18:5,956,101–6,017,839, 2 genes, copy number 13: AP001021.2, RNU5F-3P.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
